HCMI case HCM-CSHL-0839-C34 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d6164ae2-9071-418f-9682-b2ce941b02c5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1951; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.9; Tissue or organ of origin: Lung, NOS; Classification of tumor: primary; Age at diagnosis: 65.3 years (23,837 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IIIA; AJCC pathologic T: TX; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Prior treatment: Yes; Sites of involvement: Lymph Node, Subcarinal.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 217 days.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 1,106 days (3.0 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib; Treatment intent type: Neoadjuvant.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Gefitinib; Treatment intent type: Adjuvant; Initial disease status: Residual Disease.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Neoadjuvant.
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Radiation Therapy, NOS.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C79.7; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Adrenal gland, NOS; Classification of tumor: metastasis; Age at diagnosis: 68.3 years (24,951 days); Days to diagnosis: 1,114 days (3.0 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Pembrolizumab; Treatment intent type: Maintenance Therapy.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Intrathoracic lymph nodes; Days to progression: 0 days.
- Days to follow up: 1,145 days (3.1 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 1,135.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- CD274 (IHC): Positive.
- EGFR deletion: Positive; Exon: 19.
- EGFR: Negative.
- ERBB2 (IHC): Negative.
- KRAS mutation, nos: Negative.
- MET: Negative.
- RET rearrangement: Negative.
- ROS1 rearrangement (FISH): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 64.9 kg; Height: 152.4 cm; BMI: 28.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0839-C34-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0839-C34-06A-01-S1-HE: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0839-C34-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0839-C34-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0839-C34-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
